Somatic mutation profile of tumor specimen TARGET-10-PAPDVG-09A (aliquot TARGET-10-PAPDVG-09A-01D) from TARGET case TARGET-10-PAPDVG, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 7.3 years (2,675 days).
Specimen TARGET-10-PAPDVG-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 751fd06f-86ca-4832-8934-00b2d8772d29.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PAPDVG-14A (Bone Marrow Normal), aliquot TARGET-10-PAPDVG-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4c8ecdad-90a0-409a-acf0-562001dee0d6

The open-access MAF lists 12 somatic variants for this specimen: 10 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Frame Shift Ins 2, Frame Shift Del 1, 3'UTR 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AC099489.1 | c.4424C>A p.A1475E | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as rs1338222737; called by muse, mutect2, varscan2
- DSG4 | c.2224G>A p.V742I | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as rs200939281; called by muse, mutect2, varscan2
- DSTN | c.308dup p.L103Ffs*12 | Frame Shift Ins (INS) | VAF 15/89 reads (17%) | catalogued as rs750962255; called by mutect2, varscan2
- CHD7 | c.6979del p.V2327Cfs*2 | Frame Shift Del (DEL) | VAF 27/133 reads (20%) | called by mutect2, pindel, varscan2
- CNTNAP3B | c.700C>A p.L234M | Missense Mutation (SNP) | VAF 14/200 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- EDN3 | c.364G>A p.E122K | Missense Mutation (SNP) | VAF 28/127 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- IKZF1 | c.1519T>C p.S507P | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- MED12 | c.5458C>A p.L1820I | Missense Mutation (SNP) | VAF 27/90 reads (30%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.152); called by muse, mutect2, varscan2
- PHACTR4 | c.85_86insGCCC p.P29Rfs*28 (on ENST00000373839 / NM_001350159.2; = p.P39Rfs*28 on NM_023923.4) | Frame Shift Ins (INS) | VAF 9/57 reads (16%) | called by mutect2, pindel, varscan2
- SKIDA1 | c.1457A>T p.H486L | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.236); called by muse, mutect2, varscan2
- BTBD6 | c.768C>T p.A256= | Silent (SNP) | VAF 20/80 reads (25%) | catalogued as rs146708999; called by muse, mutect2, varscan2
- ELK3 | c.*71T>C | 3'UTR (SNP) | VAF 9/119 reads (8%) | catalogued as COSV99957447; called by muse, mutect2
